Surgical pathology report (de-identified scan), TCGA case TCGA-DV-A4VZ, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DV-A4VZ-01A (Primary Tumor).

[page 1 of 3]
MEDICAL RECORD**Surgical Pathology Report**UUID: 61267C95-C3D4-4262-AB18-BB21029C18CD

**Surgical Pathology Report****PATIENT:****ACCOUNT#:****DOB:****AGE:****SEX: M****ATTENDING:****REQUESTING:****CONTACT NO: (MD) -****COPIES TO:****MRN:****RECEIVED DATE:****PROCEDURE DATE:****SIGN-OUT DATE:****LOCATION:****ROOM:****DIAGNOSIS:**

1. Tumor #1, right kidney (partial nephrectomy): Renal cell carcinoma, clear cell type, Fuhrman nuclear grade 2.
2. Tumor #2, right kidney (partial nephrectomy): Renal cell carcinoma, clear cell type, Fuhrman nuclear grade 2.
3. Tumor #3, right kidney (partial nephrectomy): Renal cell carcinoma, clear cell type, Fuhrman nuclear grade 2.
4. Tumor #4, right kidney (partial nephrectomy): Renal cyst lined by clear cells.
5. 11th rib, right (resection): For gross evaluation only.

ICD-O-3

carcinoma, clear cell 8310/3

Site: kidney, NOS C64.9

hw

10/26/12

NOTE:**CLINICAL INFORMATION:** Brief Clinical History: male with bilateral renal masses, sporadic

Specimen Taken For Protocol: 01 - Yes Allocate Order to Protocol:

PROCEDURE: Operative Findings: 4 tumors right kidney Post-Operative Diagnosis:
same Pre-Operative Diagnosis: right renal masses**SPECIMENS SUBMITTED:** 1. TUMOR, # 1
2. TUMOR, # 2
3. TUMOR, # 3

Patient Identification

Surgical Pathology Report

[page 2 of 3]
MEDICAL RECORD	Surgical Pathology Report
----------------	---------------------------

Name:

Accession No.:

MRN:

4. TUMOR, # 4 Right kidney

5. RIB, Portion of right 11th

GROSS DESCRIPTION: Received are 5 containers labeled with the patient's name, medical record number, and further described as follows:

1. "Tumor #1". The specimen consists of three pieces measuring 1.4 x 0.8 x 0.7 cm in aggregate. More than 70% is solid. 60% was procured for . Piece #1 is frozen in toto; piece #2 is frozen without OCT; and part of piece #3 is fixed in glutaraldehyde and part is sent to Pathology. The procurement was performed by . In Surgical Pathology, the specimen is received as a small tan firm nodule measuring 0.9 x 0.7 x 0.4 cm. The specimen is inked in blue, bisected, revealing a tan area measuring 0.5 x 0.2 x 0.3 cm. The specimen is entirely submitted in cassette #1 for permanent processing.

2. The specimen consists of a total of six pieces measuring 3.5 x 3.5 x 2.7 cm in aggregate. More than 70% of the specimen is solid to homogeneous. 70 % was procured for . Piece #1 was frozen without OCT; piece #2-6 are frozen. The procurement was performed by . In Surgical Pathology, the specimen is received in five pieces. One piece consists of a tan membranous structure measuring 3 x 2.1 x 0.2 cm and the other four fragments are white/tan and firm and each has a big tan fibrous capsule (2 x 1 x 1 cm, 3 x 1 x 1.5 cm, 3.5 x 1.7 x 1 cm, and 3 x 2.5 x 0.6 cm). The first fragment is serially sectioned and entirely submitted in cassette . 2A and 2B. The outer surface of the other fragments is inked in blue. There is focal calcification present in one piece. The specimen is serially sectioned and entirely submitted in the following cassettes:

- . 2: Piece #2
- . D and 2E: Piece #3
- . F-2H: Piece #4 (H containing briefly decalcified section)
- . 2K: Piece #5

3. "Tumor #3". The specimen consists of a total of six pieces measuring 3.9 x 3.1 x 2.8 cm. 30-70% is cystic and solid. 70% was procured for . Piece #1 was frozen without OCT; pieces #2-5 were frozen; piece #6 was sent for permanent and a portion was fixed in glutaraldehyde. The procurement was performed by . In Surgical Pathology, the specimen is received as three white, firm pieces (2.7 x 1 x 0.5 cm, 3 x 2.5 cm, x 0.4 cm, 3 x 2.6 x 2.2 cm); two pieces have fibrous capsules with minimum attached tan tissue; and the largest fragment is 1/2 of a brown-white nodule with cystic and solid yellow cut surface. The uncut surface of the largest fragment is inked in blue. The specimen is serially sectioned and submitted in the following cassettes:

- . Piece #1
- . and 3C: Piece #2

Patient Identification

Surgical Pathology Report

[page 3 of 3]
MEDICAL RECORD	Surgical Pathology Report
----------------	---------------------------

Name:
MRN:

Accession No.:

More than 80% of piece #3

4. "Tumor #4 right kidney". The specimen consists of a single white/light tan cyst measuring 1 x 0.7 x 0.2 cm. The specimen is bisected and entirely submitted in cassette #4 for permanent processing.

5. "Portion of right 11th rib". The specimen consists of two fragments of bone, consistent with rib, measuring 2 x 1 x 0.4 cm and 2.2 x 2 x 0.5 cm. For gross evaluation only.

No consultants

Patient Identification

Surgical Pathology Report

Page 3 of 3

Source: NCI Genomic Data Commons file 99719f15-9a62-463b-acbb-28464ea21e0e (TCGA-DV-A4VZ.61267C95-C3D4-4262-AB1B-BB21029C18CD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).